Somatic mutation profile of tumor specimen TARGET-30-PASWFB-01A (aliquot TARGET-30-PASWFB-01A-01D) from TARGET case TARGET-30-PASWFB, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.0 years (727 days).
Specimen TARGET-30-PASWFB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d50ad516-b1a5-4102-b901-af8f5da78454.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASWFB-10A (Blood Derived Normal), aliquot TARGET-30-PASWFB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e0f0ed7-a205-4f25-9f72-d88893863a4c

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AXL | c.2525C>A p.P842H (on ENST00000301178 / NM_021913.5; = p.P833H on NM_001699.6) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV56571423; called by muse, mutect2, varscan2
- CDH4 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1170788458, COSV64663928; called by muse, mutect2, varscan2
- LY75 | c.4564C>T p.R1522C | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs766221795, COSV55103780; called by muse, mutect2, varscan2
- MAGEB1 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV66776124; called by muse, mutect2, varscan2
- PRKD2 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs1259313946, COSV52188197; called by muse, mutect2, varscan2
- RCC2 | c.779C>G p.A260G | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.484); catalogued as COSV64906117; called by muse, mutect2, varscan2
- STAG3 | c.569G>T p.S190I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV57932580; called by muse, mutect2, varscan2
- ZC3H12B | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs151173685; called by muse, mutect2, varscan2
- ACACA | c.4084C>T p.R1362W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- POFUT1 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- GABRG1 | c.546G>A p.L182= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV54957842; called by muse, varscan2
- NWD1 | c.1272C>A p.V424= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as COSV60346530; called by muse, mutect2, varscan2
- PLXNB1 | c.813C>T p.G271= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- TMC1 | c.1099C>T p.L367= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV52779874; called by muse, mutect2, varscan2
- TMEM200A | c.762C>G p.V254= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
